Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3380, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3380-01A (Primary Tumor).

[page 1 of 2]
Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Renal mass

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Received in a single container labeled [REDACTED] - "left kidney" is a previously partially sectioned left nephrectomy specimen surrounded by a moderate amount of partially stripped perinephric adipose tissue. The specimen as received weighs 570 grams and on reconstruction measures approximately 19.4 x 12.9 x 5.8 cm. The margin of resection include 2.5 cm of grossly patent renal artery, 1.0 cm grossly patent renal vein and 9.0 cm of grossly patent ureter. The capsule strips with ease to reveal an organ measuring on reconstruction 12.4 x 7.5 x 5.0 cm. This has a lobular homogeneous red brown outer surface. Noted on the posterior aspect in the mid region of the specimen is a 3.0 x 3.0 x 2.8 cm well circumscribed tan yellow nodular lesion with a slightly bulging focally hemorrhagic centrally hyalinized fleshy tan yellow cut surface. This appears to be thinly encapsulated. This extends beyond the plane of the cortical parenchyma but appears grossly intact with a surrounding thin layer of attenuated cortical parenchyma. The lesion appears to slightly compress the surrounding parenchyma but does not grossly appear to extend beyond the lesional capsule into this parenchyma. The remaining parenchyma shows a cortex measuring up to 0.9 cm which is homogeneous and red brown. Noted in the cortex on the antral lateral aspect in the mid region of the specimen is a 2.9 x 2.9 x 2.9 cm cystic structure with a slightly trabeculated inner gray white inner lining. Within the cystic structure is a 1.5 x 1.4 x 1.3 cm granular spiky appearing brown black calculus. The cortical medullary junction is poorly defined. The medulla is tan brown with sharp papillae. The calices and pelvis are lined by smooth tan white mucosa that extends into the ureter. Also received in the same container are two tissue cassettes each

[REDACTED] Representative sections are submitted labeled as follows: A - vascular and ureteral margins; B-E - representative lesion and surrounding tissue; F-G - representative cystic structure; H - random uninvolved parenchyma.

NOTE: Dr. [REDACTED] examined this case in the fresh state for tumor harvesting. The tumor, at the time, was noted in the periphery of the kidney and was clearly bulging above the plane of the kidney surface, however, gross extension into perinephric tissue was not appreciated.

[page 2 of 2]
Microscopic Description:

See diagnosis.

Final Diagnosis

Left nephrectomy:

Carcinoma.

Histologic type: ~~Conventional~~ (clear cell) renal carcinoma.

Tumor site: Posterior aspect in mid region.

Tumor size: 3.0 x 3.0 x 2.8 cm

Macroscopic extent of tumor: Tumor limited to kidney.

Nuclear grade: Fuhrman Grade 2/4.

Lymphovascular space invasion: No

Transcapsular invasion: No

Renal vein invasion: No

Vena caval invasion: Not resected

Adrenal gland: Not resected

Surgical margin status:

Soft tissue margins: Negative

Ureteral margin: Negative

Vascular margin: Negative

Lymph node status:

Total number of lymph nodes examined: 0

Frozen section correlation statement: None

Other significant findings: None. PAS 9

Stage: pT1

CPT: 88309

Comments

This test has been finalized at the

Electronically Signed by: #

Source: NCI Genomic Data Commons file 470c255e-c11c-4a9a-a889-724d38817f2d (TCGA-A3-3380.CC43C03D-BBBE-4563-834B-D35651F29EE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).